Somatic mutation profile of tumor specimen BA2488D (aliquot aq-BA2488D) from BEATAML1.0 case 2489, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute promyelocytic leukaemia, PML-RAR-alpha; Tissue or organ of origin: Bone marrow; Age at diagnosis: 83.6 years (30,527 days).
Specimen BA2488D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d238f0e2-de4f-4a21-a24a-9e4d7290b97b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2807D (Solid Tissue Normal), aliquot aq-BA2807D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebdd08f7-2025-4a5c-844c-287c7b14d647

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>C p.D835H | Missense Mutation (SNP) | VAF 24/152 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by mutect2, varscan2
- PANK3 | c.901A>T p.I301F | Missense Mutation (SNP) | VAF 16/100 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs77612793; called by muse, varscan2
- MAP2 | c.4834C>T p.R1612C | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761630531; called by mutect2, varscan2
- MLLT1 | c.362A>C p.K121T | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV53130614; called by muse, mutect2, varscan2
- CCDC138 | c.1076C>A p.T359N | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2
- DOCK3 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HAUS7 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KIAA1210 | c.1633T>G p.S545A | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- KLHL3 | c.1418T>C p.V473A | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- LIAS | c.391T>C p.Y131H (on ENST00000261434 / NM_001363700.2; = p.Y234H on NM_006859.4) | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- P2RY2 | c.229G>C p.V77L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SGMS2 | c.860T>C p.L287P | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZNF524 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- EDAR | c.75A>C p.R25= | Silent (SNP) | VAF 41/103 reads (40%) | called by muse, mutect2, varscan2
- DAB2IP | c.-23C>A | 5'UTR (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- SLC51A | c.288+19C>A | Intron (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
